Somatic mutation profile of tumor specimen 0DNJB9 from CCDI case PBCBHD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.8 years (4,690 days).
Specimen 0DNJB9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c015ed9-5f1d-4d95-b975-3f397e703468.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNJA3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c56b7546-ed81-4eac-92d3-343f80d95b10

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C5 | c.4570G>A p.A1524T | Missense Mutation (SNP) | VAF 112/620 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs150280452; called by muse, mutect2, varscan2
- OR51I2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 35/566 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs372469717; called by muse, mutect2
- RNF43 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 32/852 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2
- SLC11A1 | c.501-57G>A | Intron (SNP) | VAF 40/94 reads (43%) | catalogued as rs954272833; called by muse, mutect2, varscan2
